TCGA case TCGA-AX-A05Z — Uterine Corpus Endometrial Carcinoma (TCGA-UCEC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Corpus uteri; Tissue source site: Gynecologic Oncology Group. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/bf632368-8ce7-4b4b-8842-d1b1801e62ef

Demographics
Sex at birth: female; Ethnicity: hispanic or latino; Age at index: 37 years; Vital status: Alive.

Diagnoses (1)
1. Endometrioid adenocarcinoma, NOS: ICD-O-3 morphology code: 8380/3; ICD-10 code: C54.1; Tissue or organ of origin: Endometrium; Site of resection or biopsy: Endometrium; Classification of tumor: primary; Age at diagnosis: 37.0 years (13,529 days); Year of diagnosis: 2006; Method of diagnosis: Biopsy; FIGO stage: Stage IIIA; FIGO staging edition year: 1988; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1; Days to last follow up: 2,175 days (6.0 years).
   Pathology details: Lymph node involved site: Pelvis, NOS; Lymph nodes positive: 0; Lymph nodes tested: 13.
   Pathology details: Consistent pathology review: Yes; Percent tumor invasion: 50.
   Pathology details: Lymph node involved site: Aortic; Lymph nodes positive: 0; Lymph nodes tested: 7.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Days to treatment start: 61 days; Days to treatment end: 104 days; Treatment outcome: Treatment Ongoing; Clinical trial indicator: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Doxorubicin Hydrochloride; Treatment intent type: Adjuvant; Days to treatment start: 61 days; Days to treatment end: 104 days; Number of cycles: 3.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel + Pegfilgrastim; Days to treatment start: 61 days; Days to treatment end: 104 days; Treatment outcome: Treatment Ongoing; Clinical trial indicator: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Days to treatment start: 152 days; Days to treatment end: 152 days; Number of cycles: 2.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Days to treatment start: 152 days; Days to treatment end: 152 days; Treatment outcome: Treatment Ongoing; Clinical trial indicator: Yes.
   Treatment given: Treatment type: Surgery, Minimally Invasive; Initial disease status: Initial Diagnosis.
   Recorded, whether given is unknown: Pharmaceutical Therapy, NOS (Tamoxifen), prior to diagnosis.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 1,413 days (3.9 years); Disease response: Tumor Free.
- Days to follow up: 2,175 days (6.0 years); Disease response: Tumor Free.
- Peritoneal washing results: Negative; Timepoint: Initial Diagnosis.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 66 kg; Height: 150 cm; BMI: 29.3.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-AX-A05Z-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Initial weight: 180 mg.
  Slide TCGA-AX-A05Z-01A-01-BS1: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 10; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-AX-A05Z-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 10; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-AX-A05Z-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-AX-A05Z-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Menopause status: Indeterminate (neither Pre or Postmenopausal); History neoadjuvant treatment: No; Tumor status: Tumor free; Submitted tumor site: Endometrial; Histologic diagnosis: Endometrioid endometrial adenocarcinoma; Method initial path diagnosis: Office Endometrial Biopsy; Surgical approach at diagnosis: Minimally Invasive.
- Follow-up form 1: History colorectal cancer: No; Treatment outcome first course: Complete Remission/Response; Tumor status: Tumor free.
- Follow-up form 2: Lost to follow-up: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Drug treatment 1: Regimen number: 1; Pharmaceutical therapy drug name: Adriamycin.
- Drug treatment 2: Regimen number: 2; Therapy regimen: OTHER, SPECIFY IN NOTES; Therapy regimen other: Pt. request of less harsh therapy.
- Drug treatment 3: Clinical trial drug classification: adjuvent.
- Drug treatment 4: Pharmaceutical therapy drug name: taxol; Clinical trial drug classification: adjuvent.
- Drug treatment 5: Pharmaceutical therapy drug name: neulasta; Clinical trial drug classification: adjuvent.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 2,175 days; disease-specific survival: no event (censored), 2,175 days; disease-free interval: no event (censored), 2,175 days; progression-free interval: no event (censored), 2,175 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-AX-A05Z-01A-11D-A00X-01): tumor purity 0.6, ploidy 2.01, whole-genome doublings 0.
